Gene-level copy-number profile of tumor specimen TCGA-Z6-A9VB-01A from TCGA case TCGA-Z6-A9VB, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 53.3 years (19,470 days).
Specimen TCGA-Z6-A9VB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.7861363b-aa54-463a-bc70-672c4ecda241.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-Z6-A9VB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 830 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/94310ea2-7392-483f-b9a9-09b1cab412cc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 85; copy number 1: 16,959; copy number 2: 33,367; copy number 3: 7,210; copy number 4: 1,445; copy number 5: 52; copy number 6: 302; copy number 7: 182; copy number 8: 115; copy number 10: 70; copy number 12: 5; copy number 16: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-Z6-A9VB-01A-21D-A37B-01): tumor purity 0.72, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 84 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr8:2,517,898–2,728,577, 4 genes (within-gene range 0–1): AC245187.2, AC245187.1, AC245123.1, AC246817.2.
- chr9:21,135,598–26,118,408, 76 genes (within-gene range 0–12) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 727 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:163,743,913–167,259,753, 33 genes, copy number 5 (within-gene range 3–5): AC016766.1, PRPS1P1, CYP2C56P, GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F, AC019197.1, RNA5SP110, RNA5SP111, SLC38A11, SCN3A, SCN2A, MAPRE1P3, AC011303.1, CSRNP3, GALNT3, AC009495.3, AC009495.1, AC009495.2, TTC21B, TTC21B-AS1, SCN1A-AS1, SCN1A, Y_RNA, RN7SKP152, SCN9A, SCN7A, AC074101.1, XIRP2, AC092601.1, XIRP2-AS1.
- chr3:140,449,435–181,836,880, 611 genes, copy number 5–12 (within-gene range 4–12) (broad region; genes not listed).
- chr11:68,460,731–68,615,334, 1 gene, copy number 16 (within-gene range 2–16): PPP6R3.
- chr11:68,612,899–71,452,868, 68 genes, copy number 6–10 (broad region; genes not listed).
- chr11:78,139,771–78,582,156, 13 genes, copy number 7 (within-gene range 4–7): KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3.
- chr11:78,749,250–78,756,480, 1 gene, copy number 7: AP002768.1.

Autosomal genes at a single copy (total copy number 1): 14,539. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
